Somatic mutation profile of tumor specimen TCGA-OR-A5LP-01A (aliquot TCGA-OR-A5LP-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LP, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 37.2 years (13,574 days).
Specimen TCGA-OR-A5LP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 08a13de7-cfd3-47b0-aedb-9bcd1216fd27.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LP-10A (Blood Derived Normal), aliquot TCGA-OR-A5LP-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c97f9453-fb09-42ba-88d8-8bc75441309d

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 12, Silent 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL5A1 | c.2543G>A p.R848H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs767925708, COSV65664726; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IRGC | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 9/181 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs957717217, COSV54984193; called by muse, mutect2
- MAN2A1 | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54851612; called by muse, mutect2
- POM121L12 | c.329G>T p.R110L | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV68692284; called by muse, mutect2
- RBBP7 | c.755T>C p.M252T | Missense Mutation (SNP) | VAF 37/110 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs1307293598; called by muse, mutect2, varscan2
- CTH | c.1192-3_1193del p.X398_splice | Splice Site (DEL) | VAF 32/74 reads (43%) | called by mutect2, pindel, varscan2
- LRIG3 | c.2951G>A p.S984N | Missense Mutation (SNP) | VAF 72/210 reads (34%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAB21L4 | c.281T>C p.I94T | Missense Mutation (SNP) | VAF 114/179 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MKI67 | c.851C>A p.T284N | Missense Mutation (SNP) | VAF 38/65 reads (58%) | SIFT tolerated (0.11); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PALM2AKAP2 | c.987A>T p.Q329H (on ENST00000259318 / NM_001136562.3; = p.Q560H on NM_007203.5) | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RAPGEF5 | c.578A>G p.Y193C | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.9); called by muse, mutect2
- RGL1 | c.1208G>T p.R403L (on ENST00000360851 / NM_001297672.2; = p.R438L on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 55/110 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TNFRSF1A | c.865C>G p.P289A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- COBL | c.1152G>T p.V384= | Silent (SNP) | VAF 41/98 reads (42%) | catalogued as rs763150379, COSV54347204; called by muse, mutect2, varscan2
- MANBAL | c.162G>A p.P54= | Silent (SNP) | VAF 101/314 reads (32%) | catalogued as rs368166811; called by muse, mutect2, varscan2
